Somatic mutation profile of tumor specimen TARGET-10-PATFJP-09A (aliquot TARGET-10-PATFJP-09A-01D) from TARGET case TARGET-10-PATFJP, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.9 years (3,249 days).
Specimen TARGET-10-PATFJP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5bb3a47c-6b8a-47d6-95da-3b9e0da4054f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATFJP-10A (Blood Derived Normal), aliquot TARGET-10-PATFJP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19895912-ff3b-4cd5-9b49-8f97f66437ab

The open-access MAF lists 24 somatic variants for this specimen: 15 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 6, Intron 2, Frame Shift Ins 2, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CD | c.3061G>A p.E1021K | Missense Mutation (SNP) | VAF 28/87 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs397518423, CM067447, COSV63126880; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AXIN2 | c.1049C>G p.P350R | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61061482; called by muse, mutect2, varscan2
- CASKIN1 | c.1520C>T p.T507I | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58870738; called by muse, mutect2, varscan2
- COL5A3 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs752184300, COSV53419989; called by muse, mutect2, varscan2
- CYP46A1 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0.047); catalogued as COSV55896830; called by muse, mutect2, varscan2
- HAPLN1 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as rs555462462, COSV57145600; called by muse, mutect2, varscan2
- INSC | c.463G>A p.V155M | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.847); catalogued as rs753182550, COSV101088884; called by muse, varscan2
- KATNIP | c.2075T>C p.L692S | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as COSV55192714; called by muse, mutect2, varscan2
- M1AP | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51848431; called by muse, mutect2, varscan2
- MYO18B | c.3583C>T p.R1195W | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as rs373200227; called by muse, mutect2, varscan2
- NOTCH1 | c.7399_7400insGGAC p.S2467Wfs*41 | Frame Shift Ins (INS) | VAF 14/42 reads (33%) | catalogued as COSV53040674, COSV53100264; called by mutect2, pindel*, varscan2*
- OPHN1 | c.2161G>C p.D721H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.62); catalogued as COSV100830458, COSV62787266; called by muse, mutect2, varscan2
- PTEN | c.696_697insT p.R233Sfs*10 | Frame Shift Ins (INS) | VAF 74/104 reads (71%) | catalogued as COSV64288717, COSV64289856, COSV64298421, COSV64299115, COSV64306382, COSV64307526, COSV99058011, COSV99058016, COSV99058020; called by mutect2, pindel*, varscan2
- EVX2 | c.790_793delinsGACC p.M264_M265delinsDL | Missense Mutation (ONP) | VAF 7/24 reads (29%) | called by pindel, varscan2*
- LEF1 | c.319_331delinsGTTGAG p.S107Vfs*7 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | called by pindel, varscan2*
- C2orf42 | c.1614G>A p.K538= | Silent (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- FRAS1 | c.8004C>T p.N2668= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as rs886059635; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- JAG2 | c.3357G>A p.P1119= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as rs149569485; called by muse, mutect2, varscan2
- JAK2 | c.1690C>A p.R564= | Silent (SNP) | VAF 24/25 reads (96%) | catalogued as COSV67600921; called by muse, mutect2, varscan2
- KRT4 | c.1450C>T p.L484= | Silent (SNP) | VAF 32/72 reads (44%) | called by muse, mutect2, varscan2
- NUP160 | c.1986G>T p.L662= | Silent (SNP) | VAF 18/31 reads (58%) | called by muse, mutect2, varscan2
- CHMP7 | c.299+1056G>A | Intron (SNP) | VAF 9/20 reads (45%) | catalogued as rs779777359; called by muse, mutect2, varscan2
- LINC00303 | n.426C>T | RNA (SNP) | VAF 13/20 reads (65%) | catalogued as rs375816892; called by muse, mutect2, varscan2
- MRPS2 | c.44-70G>A | Intron (SNP) | VAF 7/17 reads (41%) | catalogued as rs768408278; called by muse, varscan2
